Somatic mutation profile of tumor specimen TCGA-K4-A3WV-01A (aliquot TCGA-K4-A3WV-01A-11D-A22Z-08) from TCGA case TCGA-K4-A3WV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,444 days).
Specimen TCGA-K4-A3WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b504e29-ffa8-45bc-8360-03f37323328a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K4-A3WV-10A (Blood Derived Normal), aliquot TCGA-K4-A3WV-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03d908dc-2722-438f-a3ad-b0516c4c5b35

The open-access MAF lists 66 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Nonsense Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs371492015; called by muse, mutect2
- ARID1A | c.6150G>A p.W2050* | Nonsense Mutation (SNP) | VAF 55/106 reads (52%) | catalogued as COSV100250193; called by muse, mutect2, varscan2
- BBS9 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54191315; called by muse, mutect2, varscan2
- BUD13 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755391430, COSV52770888; called by muse, mutect2, varscan2
- CADM4 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV55928255, COSV55929388, COSV55930136; called by muse, mutect2, varscan2
- CHD3 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV57881447; called by muse, mutect2, varscan2
- DMD | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63801291; called by muse, mutect2, varscan2
- DSP | c.4295A>C p.Q1432P | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV65796883; called by muse, mutect2, varscan2
- DZANK1 | c.1889A>C p.E630A (on ENST00000262547 / NM_001099407.1; = p.E437A on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV52758326; called by muse, mutect2, varscan2
- F5 | c.6228G>C p.K2076N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV63129511; called by muse, mutect2, varscan2
- FAT3 | c.13132G>A p.D4378N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs370311816; called by muse, mutect2, varscan2
- FIBIN | c.28A>C p.S10R | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as COSV59413732; called by muse, mutect2, varscan2
- FPGT | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs760356366, COSV63846268; called by muse, mutect2, varscan2
- GDF11 | c.1180G>A p.G394S | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.668); catalogued as COSV57690820; called by muse, mutect2, varscan2
- HECTD4 | c.5991G>C p.K1997N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66401425; called by muse, mutect2, varscan2
- IGSF5 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.67); catalogued as COSV66031796; called by muse, mutect2, varscan2
- IPO9 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV64236831; called by muse, mutect2, varscan2
- LCOR | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV53719391; called by muse, mutect2, varscan2
- MUC16 | c.23683C>T p.P7895S | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.155); catalogued as rs777472850, COSV67450640, COSV67501724; called by muse, mutect2, varscan2
- NCKAP5 | c.4464A>C p.Q1488H | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58459061, COSV58480613; called by muse, mutect2
- NSUN7 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV57277197; called by muse, mutect2, varscan2
- OR5M8 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367675550; called by muse, mutect2, varscan2
- PAPPA | c.4012C>G p.P1338A | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60293919; called by muse, mutect2, varscan2
- PCDHA9 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562459111, COSV65334072; called by muse, mutect2, varscan2
- PCDHA9 | c.1507T>G p.S503A | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782396245, COSV65334081; called by muse, mutect2, varscan2
- PCNX2 | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV50819686, COSV50941068; called by muse, mutect2, varscan2
- PRR7 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.045); catalogued as COSV52793964; called by muse, mutect2, varscan2
- PTPRB | c.3873C>A p.N1291K | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV54234965, COSV54234975; called by muse, mutect2, varscan2
- RIMS1 | c.706A>T p.S236C | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV53490605; called by muse, mutect2, varscan2
- RTL5 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.681); catalogued as rs765450814, COSV65455390; called by muse, mutect2, varscan2
- SCNN1D | c.1627C>T p.L543F (on ENST00000338555; = p.L707F on NM_001130413.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV57645229; called by mutect2, varscan2
- SEMA6D | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs755772605, COSV60380249; called by muse, mutect2, varscan2
- SLX4 | c.5015A>G p.H1672R | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757013389, COSV53569590; called by muse, mutect2, varscan2
- SNAPC4 | c.2972C>T p.P991L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1564378100, COSV53738800; called by muse, mutect2, varscan2
- SNIP1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV56168608; called by muse, mutect2, varscan2
- TBX22 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV64788219; called by muse, mutect2, varscan2
- TLE1 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV64686983; called by muse, mutect2, varscan2
- TOP1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63694757, COSV63696543; called by muse, varscan2
- TP53BP2 | c.2102G>A p.R701Q (on ENST00000343537 / NM_001031685.3; = p.R572Q on NM_005426.2) | Missense Mutation (SNP) | VAF 96/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59073931; called by muse, mutect2, varscan2
- TPO | c.2704G>A p.V902I | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); catalogued as rs368181428, COSV61098105; called by muse, mutect2, varscan2
- ZHX2 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs770996604, COSV58714927; called by muse, mutect2, varscan2
- ZIC1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV51553346, COSV51556481; called by muse, mutect2
- ZNF354A | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59985383; called by muse, mutect2, varscan2
- ZRANB3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV51518297; called by muse, mutect2, varscan2
- INSM2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2
- RBM17 | c.72del p.K24Nfs*9 | Frame Shift Del (DEL) | VAF 29/133 reads (22%) | called by mutect2, pindel, varscan2
- ABCC2 | c.1959A>T p.T653= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV64989013; called by muse, mutect2, varscan2
- ADAM9 | c.1425A>G p.G475= | Silent (SNP) | VAF 39/1289 reads (3%) | catalogued as COSV65963058; called by muse, mutect2
- ANO5 | c.603C>T p.I201= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs182532539, COSV61088936; called by muse, mutect2, varscan2
- BMP15 | c.1101C>T p.V367= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV53142331; called by muse, mutect2, varscan2
- C8orf74 | c.453C>T p.L151= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV58755810; called by mutect2, varscan2
- CTSW | c.375G>A p.E125= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV57173545; called by muse, mutect2, varscan2
- CYP26C1 | c.18G>A p.L6= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- DGKQ | c.897G>A p.T299= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs768767097, COSV56619222; called by muse, mutect2, varscan2
- FER1L5 | c.6234A>G p.T2078= (on ENST00000623019; = p.T2042= on NM_001293083.2) | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV53844568; called by muse, mutect2, varscan2
- JCHAIN | c.216C>A p.I72= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV54660279; called by muse, mutect2, varscan2
- KIF21A | c.852T>C p.T284= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs927384513, COSV62779167; called by muse, mutect2, varscan2
- KLK12 | c.411C>A p.G137= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV51579250; called by muse, mutect2, varscan2
- LRP1B | c.12570T>A p.S4190= | Silent (SNP) | VAF 50/86 reads (58%) | catalogued as COSV67285035; called by muse, mutect2, varscan2
- POU3F3 | c.1491G>C p.T497= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs770227812; called by muse, varscan2
- POU6F2 | c.1167G>T p.G389= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV68884104; called by muse, mutect2, varscan2
- PRKD2 | c.1545C>T p.D515= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs369924337; called by muse, mutect2, varscan2
- SLC8A3 | c.2190C>T p.Y730= (on ENST00000381269 / NM_183002.3; = p.Y728= on NM_033262.4) | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs149109491, COSV53687621; ClinVar: likely benign; called by muse, mutect2, varscan2
- SVEP1 | c.9144C>T p.A3048= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs371371607; called by muse, mutect2, varscan2
- SYMPK | c.1221G>A p.T407= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs765153097, COSV55616782; called by muse, mutect2, varscan2
- SSPOP | n.9811G>A | RNA (SNP) | VAF 12/50 reads (24%) | catalogued as rs374837960; called by muse, mutect2, varscan2
